FM case AD7539 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/6ec1605a-3bca-4629-bfef-984bca06a7bd

Female, 55.0 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the anus; metastasis biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
